Surgical pathology report (de-identified scan), TCGA case TCGA-GR-7351, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site University of Nebraska Medical Center (UNMC), specimen TCGA-GR-7351-01A (Primary Tumor).

[page 1 of 2]
Department of Pathology and Microbiology

Name: [REDACTED] Accession No: [REDACTED]
Hosp No: [REDACTED] Acct No: [REDACTED]
DOB: [REDACTED] Age: [REDACTED]
Sex: [REDACTED] Submitted by: [REDACTED]
Loc: [REDACTED] Room: [REDACTED] Client: [REDACTED]

Surgical Pathology

Final Diagnosis:

THYROID, LEFT LOBE, RESECTION: THYROID GLAND WITH DIFFUSE LARGE
B-CELL LYMPHOMA, NONCLEAVED CELL TYPE, AND LYMPHOIDITIC
THYROIDITIS. [REDACTED]

Signed: [REDACTED]

(Electronic signature)

History:

The patient is a [REDACTED]-year-old female with a history of
Hashimoto's thyroiditis and left thyroid enlargement.

Source/Gross:

LEFT THYROID: Fresh tissue is received in a container labelled
[REDACTED] and designated "left thyroid". The
specimen is a lobe of thyroid gland measuring 5.5 x 3.5 x 2.0 cm
and weighing 18.8 gm. The capsular surface is pink and
glistening. The capsular surface was inked prior to sectioning,
and the parenchyma has a nodular tan to white appearance which
involves nearly the entire lobe, with only a few scattered areas
of residual maroon thyroid parenchyma. A frozen section was
performed.

FROZEN SECTION DIAGNOSTIC: "Diagnostic material present".
Diagnosis rendered by [REDACTED] and reported to Dr.
[REDACTED]

The permanent section confirms the frozen section impression of
adequate diagnostic material.

The specimen is submitted as per the Lymphoma Study Group
Protocol:

Touch preps are made - 3.
Fixed in formalin for 24 hours - cassettes A1-A4.
Frozen in OCT for immunohistochemical studies - frozen section
block.
Placed sterily in medium for cytogenetics - 1 piece.
Frozen in foil for molecular diagnostic studies - 3 foil

These materials were examined by all those listed to establish the diagnosis with the signature being the responsible staff pathologist

[page 2 of 2]
Name:

Submitted by:

Date taken:

Accession No:

Hosp No:

Surgical Pathology

packets, each containing approximately 2.5 x 1.5 x 0.3 cm of tissue each.

Fixed in B5 - cassette A5.

These materials were examined by all those listed to establish the diagnosis, with the undersigned being the responsible staff pathologist.

Gross dictated by:

Microscopic:

IMMUNOPEROXIDASE REPORT

PARAFFIN TISSUE

B-Cell Markers	T-Cell Markers	Other Markers
CD20 (L26) +	CD45RO (A6) ND	CD45 (LCA) ND
CD79a ND	CD43 (L60) ND	CD30 (Ber-H2) ND
CD10 +	CD3 (T3) -	CD15 (Leu M1) ND
		BCR-6 +

INTERPRETATION: The paraffin markers indicate a B-cell phenotype.

Copy To:

Other Related Data:

Location:

Source: NCI Genomic Data Commons file fd7452fe-732e-4dde-8b97-d6e65038aa71 (TCGA-GR-7351.32FA61F2-A17B-40DA-B80D-1338A7BB9A7D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).